FM case AD9726 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Epithelial Neoplasms; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/80690b6e-8e4c-44f4-b281-7c1bc22d3018

Male, 86.4 years: Adenosquamous carcinoma (ICD-O-3 8560/3) of the lung; primary biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
